FM case AD211 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/1b79a23a-010a-4409-93d2-b158a8eb485b

Female, 54.1 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the head, face or neck; specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
